FM case AD7949 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Squamous Cell Neoplasms; Primary site: Penis.
https://portal.gdc.cancer.gov/cases/3420f339-cdd0-4b61-a7ba-8797dd487e9d

Male, 86.1 years: Squamous cell carcinoma, NOS (ICD-O-3 8070/3) of the penis; primary biopsied or resected from the penis. Tumor nuclei on the sequenced sample's slide: 40% (pathologist estimate recorded by GDC). Sample type: Primary Tumor.
